Somatic mutation profile of tumor specimen TARGET-30-PASVSU-09A (aliquot TARGET-30-PASVSU-09A-01D) from TARGET case TARGET-30-PASVSU, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Posterior mediastinum; Age at diagnosis: 1.8 years (652 days).
Specimen TARGET-30-PASVSU-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2d96eeeb-a609-40ac-abe2-19f7762a5822.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASVSU-10A (Blood Derived Normal), aliquot TARGET-30-PASVSU-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1e512428-13c0-490d-a14f-ceab91bb1a2c

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALK | c.3734T>G p.F1245C | Missense Mutation (SNP) | VAF 20/154 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs863225283, COSV66563458; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FASTKD1 | c.105T>A p.S35R | Missense Mutation (SNP) | VAF 8/266 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.398); called by muse, mutect2
- LRIF1 | c.166A>C p.I56L | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- USP6 | c.1065C>T p.D355= | Silent (SNP) | VAF 6/86 reads (7%) | catalogued as COSV51483508; called by muse, mutect2
- PPM1F | c.*1594A>T | 3'UTR (SNP) | VAF 8/64 reads (13%) | called by muse, mutect2
